Somatic mutation profile of tumor specimen C3L-01676-03 (aliquot CPT0172630006) from CPTAC case C3L-01676, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 53.6 years (19,568 days).
Specimen C3L-01676-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 786c0be3-af77-4179-b915-c35b169ac572.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01676-72 (Blood Derived Normal), aliquot CPT0172830002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b292ca3f-7153-4a7e-b366-07323001dd4c

The open-access MAF lists 81 somatic variants for this specimen: 55 protein-altering or splice-affecting, 13 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 13, Intron 5, Frame Shift Del 4, Nonsense Mutation 3, 3'UTR 3, In Frame Del 2, 5'Flank 2, 3'Flank 1, 5'UTR 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CB | c.3200A>T p.D1067V | Missense Mutation (SNP) | VAF 41/344 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56683107, COSV56689255; called by muse, mutect2, varscan2
- AKAP12 | c.3916G>T p.G1306C | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV99484852; called by muse, mutect2
- ANKRD28 | c.2123A>G p.H708R | Missense Mutation (SNP) | VAF 110/388 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV101080664; called by muse, mutect2, varscan2
- ATP6V0A1 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52873790; called by muse, mutect2, varscan2
- CENPK | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as COSV54468167; called by muse, mutect2
- CERKL | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 21/319 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV100183816, COSV100184315; called by muse, mutect2
- CROT | c.574A>G p.I192V | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1287841338; called by muse, mutect2, varscan2
- FBXL13 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs763963204, COSV57538615; called by muse, mutect2, varscan2
- FGD3 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs1302722786; called by muse, mutect2, varscan2
- HAUS7 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 85/165 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as rs782353201, COSV57849468; called by muse, mutect2, varscan2
- LMNB1 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 39/496 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs770347671, COSV104371970; called by muse, mutect2
- NPAT | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.308); catalogued as rs754174165, COSV53715961; called by muse, mutect2, varscan2
- OR4K15 | c.874G>T p.D292Y (on ENST00000305051; = p.D268Y on NM_001005486.1) | Missense Mutation (SNP) | VAF 64/261 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59302100; called by muse, mutect2, varscan2
- OR8B8 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 176/410 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.375); catalogued as COSV60143977; called by muse, mutect2, varscan2
- PPM1J | c.155G>T p.S52I | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV58552640; called by muse, mutect2, varscan2
- SETD2 | c.4918T>C p.W1640R | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57433720; called by muse, mutect2, varscan2
- SON | c.6185C>A p.A2062D | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.797); catalogued as COSV99279396; called by muse, mutect2
- TBX5 | c.1539G>T p.E513D | Missense Mutation (SNP) | VAF 56/608 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100090757; called by muse, mutect2
- ACO2 | c.1594_1604del p.L532Gfs*3 | Frame Shift Del (DEL) | VAF 26/244 reads (11%) | called by mutect2, pindel
- AHNAK | c.6407A>T p.D2136V | Missense Mutation (SNP) | VAF 223/733 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AKR7A2 | c.839T>A p.L280Q | Missense Mutation (SNP) | VAF 18/528 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGAP45 | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 75/285 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- ARID1A | c.5873_5891del p.E1958Gfs*51 | Frame Shift Del (DEL) | VAF 143/450 reads (32%) | called by mutect2, pindel, varscan2
- ATRX | c.4234T>G p.L1412V | Missense Mutation (SNP) | VAF 88/178 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.137); called by mutect2, varscan2
- B4GALT5 | c.563T>G p.L188R | Missense Mutation (SNP) | VAF 47/294 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC74B | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- DNAH14 | c.7653A>C p.E2551D (on ENST00000445597; = p.E3323D on NM_001367479.1) | Missense Mutation (SNP) | VAF 32/516 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2
- FBXO40 | c.152dup p.A52Gfs*57 | Frame Shift Ins (INS) | VAF 110/407 reads (27%) | called by mutect2, pindel, varscan2
- FCGBP | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); called by muse, mutect2
- GLMN | c.173_175del p.I58del | In Frame Del (DEL) | VAF 102/386 reads (26%) | called by pindel, varscan2
- GPALPP1 | c.991T>G p.F331V | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPATCH1 | c.2090G>A p.S697N | Missense Mutation (SNP) | VAF 37/246 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- GPR68 | c.960C>G p.Y320* | Nonsense Mutation (SNP) | VAF 6/93 reads (6%) | called by muse, mutect2
- HMG20A | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 67/244 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- INF2 | c.500A>G p.H167R | Missense Mutation (SNP) | VAF 148/650 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IRS4 | c.2236_2238del p.M746del | In Frame Del (DEL) | VAF 43/251 reads (17%) | called by pindel, varscan2
- JMJD1C | c.7061G>A p.G2354E | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1614 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 40/186 reads (22%) | called by muse, mutect2, varscan2
- LCE5A | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 31/410 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); called by muse, mutect2
- LLGL2 | c.2332G>T p.G778C | Missense Mutation (SNP) | VAF 17/358 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- LTN1 | c.1151A>T p.N384I | Missense Mutation (SNP) | VAF 31/319 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MVP | c.835del p.H279Tfs*5 | Frame Shift Del (DEL) | VAF 86/363 reads (24%) | called by mutect2, pindel, varscan2
- MYOC | c.1167G>C p.W389C | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDH15 | c.3419A>C p.H1140P | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PDLIM5 | c.1585+1G>T p.X529_splice | Splice Site (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- PTK7 | c.1100G>A p.G367D | Missense Mutation (SNP) | VAF 59/227 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN1A | c.2357C>G p.A786G (on ENST00000303395 / NM_001202435.3; = p.A775G on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- SPATA4 | c.400A>C p.I134L | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- TIMELESS | c.1512G>T p.E504D | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- TMPRSS13 | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 23/150 reads (15%) | called by muse, mutect2, varscan2
- TRAV39 | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 35/328 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- TTC30A | c.1418del p.N473Tfs*13 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, varscan2
- USP34 | c.10563T>A p.D3521E | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR59 | c.2399A>C p.N800T | Missense Mutation (SNP) | VAF 61/258 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBED1 | c.1375T>A p.Y459N | Missense Mutation (SNP) | VAF 203/597 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DDX20 | c.2151C>A p.I717= | Silent (SNP) | VAF 104/270 reads (39%) | called by muse, mutect2, varscan2
- ECE1 | c.1965C>T p.N655= | Silent (SNP) | VAF 20/298 reads (7%) | catalogued as rs762182710, COSV51669251; called by muse, mutect2
- GABRR1 | c.1245G>A p.E415= | Silent (SNP) | VAF 24/642 reads (4%) | catalogued as COSV101034086; called by muse, mutect2
- GALR2 | c.246G>A p.Q82= | Silent (SNP) | VAF 91/514 reads (18%) | called by muse, mutect2, varscan2
- KMT2D | c.3795A>C p.P1265= | Silent (SNP) | VAF 18/263 reads (7%) | called by muse, mutect2
- LARS1 | c.531A>T p.A177= (on ENST00000394434 / NM_020117.11; = p.A150= on NM_016460.3) | Silent (SNP) | VAF 102/386 reads (26%) | called by muse, mutect2, varscan2
- MS4A5 | c.378G>A p.L126= | Silent (SNP) | VAF 14/163 reads (9%) | catalogued as COSV100281179; called by muse, mutect2
- OBSCN | c.15249C>T p.G5083= | Silent (SNP) | VAF 66/546 reads (12%) | called by muse, mutect2, varscan2
- SYNGR4 | c.108C>T p.I36= | Silent (SNP) | VAF 23/285 reads (8%) | catalogued as rs377269157; called by muse, mutect2
- TECTA | c.4167C>T p.C1389= | Silent (SNP) | VAF 26/221 reads (12%) | catalogued as rs745818507; ClinVar: likely benign; called by mutect2, varscan2
- ZDHHC8 | c.1680G>A p.E560= | Silent (SNP) | VAF 49/329 reads (15%) | called by muse, mutect2, varscan2
- ZNF28 | c.1386T>G p.T462= | Silent (SNP) | VAF 59/252 reads (23%) | catalogued as rs756623889; called by muse, mutect2, varscan2
- ZNF398 | c.1566C>A p.R522= (on ENST00000475153 / NM_170686.3; = p.R351= on NM_020781.4) | Silent (SNP) | VAF 129/597 reads (22%) | called by muse, mutect2, varscan2
- ASH1L | chr1:155563298 G>A | 5'Flank (SNP) | VAF 72/273 reads (26%) | called by muse, mutect2, varscan2
- BPIFB2 | c.*15G>T | 3'UTR (SNP) | VAF 41/367 reads (11%) | called by muse, mutect2, varscan2
- C9orf62 | n.168G>A | RNA (SNP) | VAF 9/199 reads (5%) | called by muse, mutect2
- FBXO28 | c.516+15C>G | Intron (SNP) | VAF 34/208 reads (16%) | called by muse, mutect2, varscan2
- GLYCTK | c.*843C>A | 3'UTR (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- KLHL29 | c.940+37C>T | Intron (SNP) | VAF 12/178 reads (7%) | catalogued as rs1265178024; called by muse, mutect2
- LSM14B | c.427+1152del | Intron (DEL) | VAF 44/383 reads (11%) | called by mutect2, pindel, varscan2
- MYLPF | c.406-21C>G | Intron (SNP) | VAF 13/211 reads (6%) | called by muse, mutect2
- PLRG1 | c.*82C>T | 3'UTR (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2
- RGL1 | chr1:183930223 G>T | 3'Flank (SNP) | VAF 43/291 reads (15%) | called by muse, mutect2, varscan2
- SH3GL3 | c.45+43322C>A | Intron (SNP) | VAF 24/145 reads (17%) | called by muse, mutect2, varscan2
- SLC25A26 | c.-74G>C | 5'UTR (SNP) | VAF 84/266 reads (32%) | called by muse, mutect2, varscan2
- TSLP | chr5:111071459 C>T | 5'Flank (SNP) | VAF 19/78 reads (24%) | catalogued as rs566158190; called by muse, mutect2, varscan2
